Somatic mutation profile of tumor specimen TCGA-BR-A4J2-01A (aliquot TCGA-BR-A4J2-01A-21D-A25D-08) from TCGA case TCGA-BR-A4J2, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 70.9 years (25,891 days).
Specimen TCGA-BR-A4J2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a7bcb50-89ec-4000-a94d-350b4b74c4aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4J2-10A (Blood Derived Normal), aliquot TCGA-BR-A4J2-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/349a2afb-0c82-4e21-8387-e143fc70336a

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 20, Silent 14, Nonsense Mutation 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS2 | c.1146T>G p.F382L | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV53625534; called by muse, mutect2, varscan2
- BBS10 | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs907797872, COSV99675016; called by muse, mutect2
- CD6 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs763287629, COSV57839708; called by muse, mutect2
- CSRNP3 | c.1199A>G p.H400R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs1178463409, COSV58779914; called by muse, mutect2, varscan2
- DHX38 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs747622765, COSV51697841; called by muse, mutect2, varscan2
- DNAH7 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs370071352; called by muse, mutect2, varscan2
- EDC3 | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.901); catalogued as COSV100165945; called by muse, mutect2
- KCNK4 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as rs376946590; called by muse, mutect2, varscan2
- KLHL24 | c.673A>C p.K225Q | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.309); catalogued as COSV54426878; called by muse, mutect2
- KRTAP3-1 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.042); catalogued as rs1413273289, COSV101196077; called by muse, mutect2
- MAP7D2 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV65528045; called by muse, mutect2, varscan2
- MRAS | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.153); catalogued as rs779616242, COSV56672239; called by mutect2, varscan2
- NLRP14 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1268394465, COSV55063572, COSV55068248; called by muse, mutect2
- NSMF | c.702A>G p.Q234= | Splice Region (SNP) | VAF 18/284 reads (6%) | catalogued as COSV53000543; called by muse, mutect2
- OR6N2 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 12/153 reads (8%) | catalogued as COSV59411511, COSV59411841; called by muse, mutect2
- PCDHA11 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV56514390; called by muse, mutect2
- PI15 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as COSV52642251; called by muse, mutect2
- RB1 | c.1331A>T p.Q444L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as CS004739, COSV57295348, COSV57299699; called by muse, mutect2, varscan2
- RHOV | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV99592093; called by muse, mutect2
- SAFB | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1360424562, COSV52651910; called by muse, mutect2, varscan2
- SLC12A5 | c.409G>A p.V137I (on ENST00000454036 / NM_001134771.2; = p.V114I on NM_020708.5) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as rs760750912, COSV54790791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPO | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.012); catalogued as rs750068617, COSV61094907; called by muse, mutect2
- ERCC6 | c.2286+1G>T p.X762_splice | Splice Site (SNP) | VAF 9/243 reads (4%) | called by muse, mutect2
- IGDCC4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- USP10 | c.1678A>C p.K560Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.033); called by muse, mutect2
- ANKRD13A | c.1530G>A p.S510= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as rs377322373, COSV55677211; called by muse, mutect2
- ATM | c.2268A>T p.A756= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV53750892; called by muse, mutect2
- CD1D | c.126G>A p.T42= | Silent (SNP) | VAF 39/255 reads (15%) | catalogued as COSV63809243; called by muse, mutect2, varscan2
- CIZ1 | c.1605G>A p.A535= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as rs550697095, COSV52972192; called by muse, mutect2
- DCC | c.1884C>T p.N628= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as rs1244338605, COSV59109923; called by muse, mutect2
- DLL1 | c.2079C>T p.D693= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as rs1190931931, COSV64537783; called by muse, mutect2, varscan2
- GRIN2A | c.1425C>T p.Y475= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs774228933, COSV58020959; ClinVar: likely benign; called by muse, mutect2, varscan2
- HTR1B | c.525C>T p.V175= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV64051773; called by muse, mutect2
- PCDHB11 | c.1965C>T p.T655= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as rs537668658, COSV61312276; called by muse, mutect2
- PCDHB6 | c.711C>T p.N237= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV50702286, COSV50709742; called by muse, mutect2
- PLXNB3 | c.2358C>T p.Y786= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs782041448, COSV62798391; called by muse, mutect2, varscan2
- PRAMEF17 | c.1005C>T p.T335= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as COSV101068728; called by muse, mutect2
- SPTA1 | c.4350C>A p.I1450= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs757971123, COSV100934900; called by mutect2, varscan2
- TTN | c.21690T>G p.T7230= (on ENST00000591111; = p.T6303= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as COSV60134886; called by muse, mutect2
